CCDI case PBCRAW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/057302f3-e65c-437e-8169-7a80070124ca

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Atypical meningioma: ICD-O-3 morphology code: 9539/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.2 years (6,647 days).

Biospecimens (3 samples)
- Sample 0DX4EW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4F9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX4FW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
